Somatic mutation profile of tumor specimen C3L-04038-01 (aliquot CPT0256720007) from CPTAC case C3L-04038, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 81.1 years (29,612 days).
Specimen C3L-04038-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 79392309-ced2-4d42-bea7-791f283edc0b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04038-31 (Blood Derived Normal), aliquot CPT0256820002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2650982a-8af4-4293-b9bb-31f98ae956ac

The open-access MAF lists 90 somatic variants for this specimen: 52 protein-altering or splice-affecting, 28 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 28, Intron 6, Nonsense Mutation 4, 3'UTR 3, Splice Region 3, Frame Shift Del 3, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- F8 | c.43C>T p.R15* | Nonsense Mutation (SNP) | VAF 129/338 reads (38%) | catalogued as rs387906432, CM900085, COSV64270158; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATAD3B | c.527C>T p.P176L (on ENST00000308647; = p.P282L on NM_031921.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 146/413 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as rs749396117; called by muse, mutect2, varscan2
- ATP6V0D2 | c.197C>T p.T66I | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); catalogued as rs1409996410; called by muse, mutect2
- CASTOR1 | c.505+3G>A | Splice Region (SNP) | VAF 18/45 reads (40%) | catalogued as rs377420987; called by muse, mutect2, varscan2
- CILP | c.2183C>T p.T728I | Missense Mutation (SNP) | VAF 60/182 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as rs142177709; called by muse, mutect2, varscan2
- COL4A4 | c.2420G>A p.G807D | Missense Mutation (SNP) | VAF 134/391 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CD1313492; called by muse, mutect2, varscan2
- DNAH3 | c.2774G>A p.R925H | Missense Mutation (SNP) | VAF 75/265 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs774946198, COSV54523207; called by muse, mutect2, varscan2
- FAT3 | c.2914C>T p.R972C | Missense Mutation (SNP) | VAF 45/136 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs146432830; called by muse, mutect2, varscan2
- FMR1 | c.1591G>A p.G531R | Missense Mutation (SNP) | VAF 62/160 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as rs1557181631, COSV54427846; called by muse, mutect2, varscan2
- KSR2 | c.919G>A p.A307T | Missense Mutation (SNP) | VAF 231/442 reads (52%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as rs778527288, COSV60370762; called by muse, mutect2, varscan2
- LGALS14 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 57/271 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs111361406, COSV62372178; called by muse, mutect2, varscan2
- MPP4 | c.1283G>A p.R428H | Missense Mutation (SNP) | VAF 59/139 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770767656; called by muse, mutect2, varscan2
- MUC12 | c.953C>T p.T318M (on ENST00000379442; = p.T175M on NM_001164462.1) | Missense Mutation (SNP) | VAF 158/611 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.95); catalogued as rs769176549, COSV65182189; called by muse, mutect2, varscan2
- MUC7 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 67/211 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.16); catalogued as rs772332674, COSV59218518; called by muse, mutect2, varscan2
- MYH1 | c.1573G>A p.E525K | Missense Mutation (SNP) | VAF 84/252 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.738); catalogued as rs150654605; called by muse, mutect2, varscan2
- NLRP11 | c.816G>A p.W272* | Nonsense Mutation (SNP) | VAF 57/222 reads (26%) | catalogued as COSV64087413; called by muse, mutect2, varscan2
- PCDH11X | c.1894G>A p.D632N | Missense Mutation (SNP) | VAF 58/175 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771550178, COSV53465556; called by muse, mutect2, varscan2
- PKHD1L1 | c.4960C>T p.R1654* | Nonsense Mutation (SNP) | VAF 67/164 reads (41%) | catalogued as rs557260323, COSV65751300; called by muse, mutect2, varscan2
- PRR12 | c.2261G>A p.R754Q (on ENST00000615927; = p.R1575Q on NM_020719.3) | Missense Mutation (SNP) | VAF 176/602 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV69819576; called by muse, mutect2, varscan2
- SEC14L5 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 56/147 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs774706819, COSV52039395; called by muse, mutect2, varscan2
- SLC5A6 | c.1208-3C>T | Splice Region (SNP) | VAF 32/104 reads (31%) | catalogued as rs950369577; called by muse, mutect2
- SORCS1 | c.1184G>A p.R395Q | Missense Mutation (SNP) | VAF 17/174 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as rs575431793, COSV53854383; called by muse, mutect2
- TRPM1 | c.2999G>A p.R1000Q | Missense Mutation (SNP) | VAF 49/168 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs374787557; called by muse, mutect2, varscan2
- TUBB4A | c.1078G>A p.G360S | Missense Mutation (SNP) | VAF 189/590 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV51152526; called by muse, mutect2, varscan2
- ZNF229 | c.1810G>A p.V604M | Missense Mutation (SNP) | VAF 68/254 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.273); catalogued as rs752215607, COSV52159867; called by muse, mutect2, varscan2
- CCER1 | c.715G>A p.G239S | Missense Mutation (SNP) | VAF 97/197 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- CNGB3 | c.2309_2312del p.V770Efs*58 | Frame Shift Del (DEL) | VAF 37/99 reads (37%) | called by mutect2, pindel, varscan2
- FAM120C | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 104/274 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.994); called by muse, varscan2
- FNDC7 | c.789G>C p.L263F | Missense Mutation (SNP) | VAF 46/145 reads (32%) | SIFT tolerated (0.68); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FOXN1 | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 51/161 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- GNL3L | c.456C>G p.C152W | Missense Mutation (SNP) | VAF 50/185 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ITGA8 | c.3022T>A p.F1008I | Missense Mutation (SNP) | VAF 6/148 reads (4%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.834); called by muse, mutect2
- ITPRID1 | c.681C>G p.N227K | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- ITPRID1 | c.2713G>A p.E905K | Missense Mutation (SNP) | VAF 9/183 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.12); called by muse, mutect2
- LYPD2 | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 72/222 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.341); called by muse, mutect2
- MANBA | c.2701T>G p.F901V (on ENST00000642252; = p.F855V on NM_005908.4) | Missense Mutation (SNP) | VAF 98/261 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MIA | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 74/317 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- PCLO | c.15163G>T p.V5055L | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PDIA5 | c.164A>G p.K55R | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PIK3C2G | c.86A>C p.Q29P | Missense Mutation (SNP) | VAF 14/171 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); called by muse, mutect2
- PPP4R1 | c.2525_2529del p.Q842Lfs*10 (on ENST00000400556 / NM_001042388.3; = p.Q825Lfs*10 on NM_005134.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 66/192 reads (34%) | called by mutect2, pindel, varscan2
- PPP6R3 | c.351T>A p.N117K | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- PTGER2 | c.846T>A p.I282= | Splice Region (SNP) | VAF 34/92 reads (37%) | called by muse, mutect2
- RTTN | c.5130A>T p.K1710N | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- SLC11A2 | c.1075G>T p.V359L (on ENST00000394904 / NM_001379455.1; = p.V330L on NM_000617.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 162/343 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- STARD9 | c.3553G>A p.G1185S | Missense Mutation (SNP) | VAF 128/358 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- TEX15 | c.3380G>T p.C1127F (on ENST00000256246; = p.C1510F on NM_001350162.2) | Missense Mutation (SNP) | VAF 62/152 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- TTC6 | c.241G>A p.G81S | Missense Mutation (SNP) | VAF 18/231 reads (8%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0.059); called by muse, mutect2
- USP9X | c.7651C>T p.R2551* | Nonsense Mutation (SNP) | VAF 51/149 reads (34%) | called by muse, mutect2, varscan2
- VCPIP1 | c.1856A>C p.N619T | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ZFHX4 | c.10045A>G p.T3349A | Missense Mutation (SNP) | VAF 84/260 reads (32%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF780B | c.1085_1088del p.E362Afs*52 | Frame Shift Del (DEL) | VAF 83/343 reads (24%) | called by mutect2, pindel, varscan2
- ACP7 | c.1245C>T p.D415= | Silent (SNP) | VAF 73/216 reads (34%) | catalogued as rs563661468; called by muse, mutect2, varscan2
- ADAMTS17 | c.2271A>C p.P757= | Silent (SNP) | VAF 17/478 reads (4%) | called by muse, mutect2
- BEX1 | c.186T>C p.Y62= | Silent (SNP) | VAF 99/253 reads (39%) | called by muse, mutect2, varscan2
- CD209 | c.834C>T p.H278= | Silent (SNP) | VAF 55/175 reads (31%) | catalogued as rs61742035, COSV52654363; called by muse, mutect2, varscan2
- CNTNAP2 | c.3561C>T p.I1187= | Silent (SNP) | VAF 118/485 reads (24%) | catalogued as rs775209615, COSV62192752, COSV62265806; called by muse, mutect2, varscan2
- DPPA3 | c.57C>T p.T19= | Silent (SNP) | VAF 61/280 reads (22%) | catalogued as COSV61503020; called by muse, mutect2, varscan2
- DSG4 | c.789C>T p.N263= | Silent (SNP) | VAF 84/264 reads (32%) | catalogued as rs148802079; called by muse, mutect2, varscan2
- EPHA8 | c.2859G>A p.A953= | Silent (SNP) | VAF 160/471 reads (34%) | catalogued as rs768364715; called by muse, varscan2
- GUCY2F | c.2076C>T p.N692= | Silent (SNP) | VAF 43/125 reads (34%) | catalogued as rs749119684, COSV54308865; called by muse, mutect2, varscan2
- LAMB1 | c.84C>T p.Y28= | Silent (SNP) | VAF 47/219 reads (21%) | called by muse, mutect2, varscan2
- MCM7 | c.942T>C p.S314= | Silent (SNP) | VAF 57/266 reads (21%) | called by muse, mutect2, varscan2
- NLRP5 | c.3258C>T p.C1086= | Silent (SNP) | VAF 57/212 reads (27%) | catalogued as rs764666206, COSV66763493; called by muse, mutect2, varscan2
- NSUN2 | c.1842T>C p.F614= | Silent (SNP) | VAF 29/68 reads (43%) | called by muse, mutect2, varscan2
- OR2J2 | c.852G>T p.P284= | Silent (SNP) | VAF 29/160 reads (18%) | called by muse, mutect2, varscan2
- OR5L2 | c.114G>A p.T38= | Silent (SNP) | VAF 54/171 reads (32%) | catalogued as rs1342063295; called by muse, mutect2, varscan2
- OTOA | c.1026G>A p.L342= (on ENST00000286149; = p.L328= on NM_144672.4) | Silent (SNP) | VAF 199/492 reads (40%) | catalogued as rs764851693; called by muse, mutect2, varscan2
- PNN | c.1395A>G p.E465= | Silent (SNP) | VAF 39/107 reads (36%) | called by muse, mutect2, varscan2
- RIMBP3 | c.3636C>T p.P1212= | Silent (SNP) | VAF 32/239 reads (13%) | catalogued as rs1459833192; called by mutect2, varscan2
- SERINC1 | c.75A>G p.L25= | Silent (SNP) | VAF 33/53 reads (62%) | catalogued as rs147867146; called by muse, mutect2, varscan2
- SERPINA10 | c.819C>T p.G273= | Silent (SNP) | VAF 94/248 reads (38%) | called by muse, mutect2, varscan2
- SOX3 | c.42G>A p.P14= | Silent (SNP) | VAF 203/589 reads (34%) | catalogued as rs763427220, COSV65168259; called by muse, mutect2, varscan2
- STAT5A | c.1872C>T p.I624= | Silent (SNP) | VAF 74/179 reads (41%) | catalogued as rs143308879; called by muse, mutect2, varscan2
- TBX18 | c.1692G>A p.T564= | Silent (SNP) | VAF 99/187 reads (53%) | catalogued as rs757361472, COSV63736613, COSV63737169; called by muse, mutect2, varscan2
- TNNI3K | c.2301C>T p.F767= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as rs761994983, COSV53947073; called by muse, mutect2, varscan2
- TPO | c.2133C>T p.V711= | Silent (SNP) | VAF 124/382 reads (32%) | catalogued as rs377151900; called by muse, mutect2
- TTC6 | c.3045G>A p.T1015= | Silent (SNP) | VAF 48/146 reads (33%) | catalogued as rs565996852; called by muse, mutect2, varscan2
- UGT2B4 | c.192C>T p.F64= | Silent (SNP) | VAF 43/126 reads (34%) | catalogued as rs376830467; called by muse, mutect2, varscan2
- ZNF761 | c.972A>G p.K324= | Silent (SNP) | VAF 101/357 reads (28%) | called by muse, mutect2, varscan2
- ANK3 | c.13065+1941C>T | Intron (SNP) | VAF 34/60 reads (57%) | catalogued as rs774647799, COSV99779186; called by muse, mutect2, varscan2
- CHODL | c.-24A>T | 5'UTR (SNP) | VAF 137/365 reads (38%) | called by muse, mutect2, varscan2
- FAM161A | c.1683+30G>A | Intron (SNP) | VAF 42/119 reads (35%) | catalogued as rs200959427; called by muse, mutect2, varscan2
- FOXP2 | c.*2564T>C | 3'UTR (SNP) | VAF 34/145 reads (23%) | called by muse, mutect2, varscan2
- FOXP2 | c.*3163G>C | 3'UTR (SNP) | VAF 70/228 reads (31%) | called by muse, mutect2, varscan2
- FOXRED1 | c.306+54_306+58del | Intron (DEL) | VAF 58/177 reads (33%) | called by mutect2, pindel, varscan2
- PKD1 | c.11016+45T>G | Intron (SNP) | VAF 41/91 reads (45%) | called by muse, mutect2, varscan2
- RALGDS | c.2569+34G>A | Intron (SNP) | VAF 89/271 reads (33%) | called by muse, mutect2, varscan2
- SYNE3 | c.790-56A>T | Intron (SNP) | VAF 14/46 reads (30%) | catalogued as rs776977797; called by muse, varscan2
- TGFBR3 | c.*1682A>T | 3'UTR (SNP) | VAF 70/182 reads (38%) | catalogued as rs1022463466; called by mutect2, varscan2
